Somatic mutation profile of tumor specimen MMRF_2455_1_BM_CD138pos (aliquot MMRF_2455_1_BM_CD138pos_T1_KHS5U_L11225) from MMRF case MMRF_2455, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.1 years (23,048 days).
Specimen MMRF_2455_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 720da909-5eb2-4253-997d-fbf849540d25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2455_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2455_1_PB_Whole_C3_KHS5U_L11226; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/79de66ce-ed1d-4caa-8d5c-a2b2b37e1383

The open-access MAF lists 512 somatic variants for this specimen: 157 protein-altering or splice-affecting, 74 silent, 281 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 144, Missense Mutation 139, Intron 74, Silent 74, 5'UTR 38, 5'Flank 15, Nonsense Mutation 9, RNA 6, Splice Site 5, 3'Flank 4, Splice Region 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 38/57 reads (67%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ACSM3 | c.649G>A p.D217N | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT tolerated (0.45); PolyPhen benign (0.197); catalogued as COSV104389040; called by muse, mutect2, varscan2
- ADGRA3 | c.3643G>A p.E1215K | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1404660498, COSV99292871; called by muse, mutect2, varscan2
- AGTR1 | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763952495, COSV62557123; called by muse, mutect2, varscan2
- ARID4A | c.1131G>T p.L377F | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355223338; called by muse, mutect2
- ASPM | c.4166C>G p.S1389C | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV99659442; called by muse, mutect2, varscan2
- ATP1A3 | c.1845+1G>A p.X615_splice (on ENST00000545399 / NM_001256214.2; = p.X602_splice on NM_152296.5) | Splice Site (SNP) | VAF 56/130 reads (43%) | catalogued as COSV57485789; called by muse, mutect2, varscan2
- ATP8B1 | c.109G>C p.G37R | Missense Mutation (SNP) | VAF 39/270 reads (14%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.006); catalogued as rs904280533; called by muse, mutect2, varscan2
- BCAS3 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV66777420; called by muse, mutect2, varscan2
- C20orf203 | c.461C>T p.S154L | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.514); catalogued as rs554343704; called by muse, mutect2, varscan2
- CCDC138 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV99719239; called by muse, mutect2, varscan2
- CCPG1 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374529704; called by muse, mutect2, varscan2
- CWF19L1 | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62499634; called by muse, mutect2, varscan2
- DLC1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV52305027; called by muse, mutect2, varscan2
- DLGAP5 | c.740G>A p.R247K | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs1196852164; called by muse, mutect2, varscan2
- DNAH5 | c.1153C>T p.H385Y | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as rs746195871, COSV54201763; called by muse, mutect2, varscan2
- ESRP2 | c.1553C>T p.S518L (on ENST00000565858 / NM_001365264.1; = p.S508L on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/110 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs143677348; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EVI2A | c.626T>A p.M209K | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs759197449; called by muse, mutect2, varscan2
- FOLH1 | c.1513G>C p.E505Q | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs1167308324; called by muse, mutect2, varscan2
- GALR1 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 46/145 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as COSV55318023; called by muse, mutect2, varscan2
- GIPC2 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs143579527; called by muse, mutect2, varscan2
- GLIS3 | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 74/283 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs758121146, COSV60938169, COSV60938434; called by muse, mutect2, varscan2
- GYS2 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 84/160 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1284586998, COSV53923687; called by muse, mutect2, varscan2
- HDLBP | c.1293+1G>C p.X431_splice | Splice Site (SNP) | VAF 69/163 reads (42%) | catalogued as rs113965743, COSV100191197; called by muse, mutect2, varscan2
- IGHV2-70 | c.346T>C p.C116R | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs570255228; called by muse, varscan2
- IGLV4-60 | c.332A>T p.Y111F | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs773941580; called by muse, varscan2
- IGLV4-69 | c.331T>C p.Y111H | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.476); catalogued as rs372708335; called by muse, mutect2, varscan2
- IGLV6-57 | c.287C>T p.T96I | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); catalogued as rs781649738; called by muse, varscan2
- JOSD1 | c.440G>A p.G147E | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0.043); catalogued as COSV99320155; called by muse, mutect2, varscan2
- KIAA1549L | c.4784C>T p.P1595L (on ENST00000321505; = p.P1892L on NM_012194.3) | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762094891, COSV100382222; called by muse, varscan2
- KIT | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 86/176 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.01); catalogued as COSV55388771, COSV55404917; called by muse, mutect2, varscan2
- LRRC61 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 100/149 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as rs770559995; called by muse, mutect2, varscan2
- MARCO | c.1345G>A p.D449N | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59055478; called by muse, mutect2, varscan2
- MMRN1 | c.106C>G p.Q36E | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.026); catalogued as COSV99306234; called by muse, mutect2, varscan2
- MPPED2 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.178); catalogued as COSV100813352; called by muse, mutect2, varscan2
- NASP | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV100601803; called by muse, mutect2, varscan2
- NDUFAF6 | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs776291020; called by muse, varscan2
- NLRP9 | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 50/99 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV60460162, COSV60463028; called by muse, mutect2, varscan2
- NOTCH4 | c.5506G>A p.E1836K | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0.015); catalogued as rs1253487294, COSV66679424, COSV66679988, COSV66681239; called by muse, mutect2, varscan2
- NUDT12 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.036); catalogued as COSV100048161; called by muse, mutect2, varscan2
- OPN5 | c.686C>T p.S229F | Missense Mutation (SNP) | VAF 78/166 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV55245977; called by muse, mutect2, varscan2
- PCBP1 | c.607G>C p.D203H | Missense Mutation (SNP) | VAF 31/57 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.275); catalogued as COSV57851758; called by muse, mutect2, varscan2
- PLEKHJ1 | c.51G>C p.E17D | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.026); catalogued as rs1300105591, COSV55553921; called by muse, mutect2, varscan2
- PLXNA3 | c.1002G>C p.Q334H | Missense Mutation (SNP) | VAF 104/112 reads (93%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.807); catalogued as rs1557204488; called by muse, mutect2, varscan2
- PLXNA4 | c.4438G>A p.E1480K | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs774839624, COSV58118492; called by muse, mutect2, varscan2
- PSRC1 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as rs144416204; called by muse, mutect2, varscan2
- PTPRD | c.733C>T p.H245Y | Missense Mutation (SNP) | VAF 70/205 reads (34%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as COSV61936769; called by muse, mutect2, varscan2
- SELENOT | c.559A>G p.M187V | Missense Mutation (SNP) | VAF 82/255 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.678); catalogued as rs1235846947, COSV71982259; called by muse, mutect2, varscan2
- SGK2 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs140303557; called by muse, mutect2, varscan2
- SORCS1 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 88/171 reads (51%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.015); catalogued as COSV53890178; called by muse, mutect2, varscan2
- SPG11 | c.3883G>A p.E1295K | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.406); catalogued as COSV55995942; called by muse, mutect2, varscan2
- SPTY2D1 | c.1573A>G p.S525G | Missense Mutation (SNP) | VAF 49/97 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1471065759; called by muse, mutect2, varscan2
- SRRM3 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.841); catalogued as rs1554608297; called by muse, mutect2, varscan2
- TAF1A | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 225/467 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV100601166; called by muse, mutect2, varscan2
- THAP9 | c.1031G>C p.R344T | Missense Mutation (SNP) | VAF 81/182 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1051655356; called by muse, mutect2, varscan2
- TLCD5 | c.689G>A p.R230Q (on ENST00000375095 / NM_001198671.2; = p.R133Q on NM_174926.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs991960155; called by muse, mutect2, varscan2
- TNKS | c.1984G>A p.D662N | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.092); catalogued as rs1363583222; called by muse, mutect2, varscan2
- TREM2 | c.123G>A p.M41I | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV100632523; called by muse, mutect2, varscan2
- USP42 | c.3931G>C p.E1311Q | Missense Mutation (SNP) | VAF 113/315 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.096); catalogued as COSV100084677; called by muse, mutect2, varscan2
- ZC3H11B | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 48/134 reads (36%) | catalogued as COSV65844808; called by muse, mutect2, varscan2
- ZC3H6 | c.996C>G p.F332L | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.068); catalogued as COSV59667114; called by muse, mutect2, varscan2
- ZNF148 | c.1427A>T p.Y476F | Missense Mutation (SNP) | VAF 98/157 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV62305412; called by muse, mutect2, varscan2
- ZNF251 | c.401G>A p.R134Q | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs377584380; called by muse, mutect2
- ZNF618 | c.1043G>A p.R348H (on ENST00000374126 / NM_001318042.2; = p.R316H on NM_001318040.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 172/285 reads (60%) | SIFT tolerated, low confidence (0.35); PolyPhen probably damaging (0.964); catalogued as rs1198668904; called by mutect2, varscan2
- ZNF860 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 62/243 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1247937977, COSV64384460; called by muse, mutect2, varscan2
- AC090517.4 | c.302C>G p.S101C | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ACTL8 | c.419C>A p.S140Y | Missense Mutation (SNP) | VAF 49/91 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ADCY10 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 194/490 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ANKRD30B | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 17/63 reads (27%) | called by muse, mutect2, varscan2
- ANKRD34C | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 73/183 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- ARMC3 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- ARSL | c.1698G>A p.W566* | Nonsense Mutation (SNP) | VAF 57/58 reads (98%) | called by muse, mutect2, varscan2
- ASPDH | c.478G>A p.E160K (on ENST00000389208 / NM_001114598.2; = p.E55K on NM_001024656.3) | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- BMPR1B | c.1238G>A p.R413K | Missense Mutation (SNP) | VAF 54/120 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- C11orf54 | c.25C>T p.H9Y | Missense Mutation (SNP) | VAF 69/134 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CAND1 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- CCDC185 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT tolerated (0.52); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- COL23A1 | c.295-1G>T p.X99_splice | Splice Site (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- CPB1 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CRY1 | c.1658G>A p.G553E | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- CYTH1 | c.926A>C p.N309T | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- DNAI3 | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 116/261 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- DZANK1 | c.1570G>A p.E524K (on ENST00000262547 / NM_001099407.1; = p.E331K on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/112 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- EOMES | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); called by muse, varscan2
- ERBB2 | c.2888C>G p.S963C | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- FAM3D | c.236G>A p.G79D | Missense Mutation (SNP) | VAF 35/112 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAR2 | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 101/206 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- FMNL2 | c.1375G>C p.E459Q | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- FSIP2 | c.12643G>A p.D4215N | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- GABARAP | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 57/81 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- GJA8 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 157/339 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- GLIPR1L2 | c.796C>A p.L266M | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- GULP1 | c.170G>A p.R57K | Missense Mutation (SNP) | VAF 98/242 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- HMGN1 | c.79-1G>C p.X27_splice | Splice Site (SNP) | VAF 36/84 reads (43%) | called by muse, mutect2, varscan2
- IFRD1 | c.-179C>T | Splice Region (SNP) | VAF 67/204 reads (33%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.296T>C p.V99A | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, varscan2
- KLHL12 | c.1325C>G p.S442* | Nonsense Mutation (SNP) | VAF 39/250 reads (16%) | called by muse, mutect2, varscan2
- LATS1 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 82/161 reads (51%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- LBP | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- LMNTD1 | c.922C>G p.Q308E | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LONRF1 | c.1798C>T p.Q600* | Nonsense Mutation (SNP) | VAF 80/212 reads (38%) | called by muse, varscan2
- LRBA | c.1474G>T p.E492* | Nonsense Mutation (SNP) | VAF 17/33 reads (52%) | called by muse, mutect2, varscan2
- LRP1B | c.1394G>A p.R465K | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- MAFB | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- MAGED1 | c.1550G>A p.C517Y | Missense Mutation (SNP) | VAF 49/53 reads (92%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- MCM5 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MFSD14A | c.390C>G p.I130M | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- MLLT3 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- MON1A | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MPEG1 | c.1487C>T p.S496L | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- NKD2 | c.407G>A p.C136Y | Missense Mutation (SNP) | VAF 33/65 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- NKD2 | c.553G>T p.E185* | Nonsense Mutation (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
- NOS2 | c.2077C>G p.Q693E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.9); PolyPhen benign (0.001); called by muse, mutect2
- NPAS4 | c.209C>G p.S70* | Nonsense Mutation (SNP) | VAF 37/75 reads (49%) | called by muse, mutect2, varscan2
- NRDE2 | c.909G>C p.E303D | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- OBSCN | c.22957+2T>C p.X7653_splice | Splice Site (SNP) | VAF 15/138 reads (11%) | called by muse, mutect2, varscan2
- ORC3 | c.293G>C p.R98T | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- PCDHGC3 | c.100C>T p.H34Y | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- PHETA2 | c.238C>A p.P80T | Missense Mutation (SNP) | VAF 66/130 reads (51%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- POLR1E | c.1093C>A p.P365T (on ENST00000377792 / NM_001282766.1; = p.P303T on NM_022490.4) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLR1H | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- POU1F1 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- PRKD3 | c.1079C>T p.T360I | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRSS12 | c.2040-3C>T | Splice Region (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- RAF1 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RBM7 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 81/169 reads (48%) | called by muse, mutect2, varscan2
- RPAP2 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT tolerated (0.73); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RSC1A1 | c.57G>C p.Q19H | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SCX | c.511G>C p.E171Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SEC24A | c.1183C>G p.Q395E | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SEC24D | c.2252A>G p.Y751C | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SELENBP1 | c.711G>C p.E237D | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- SFRP1 | c.318C>A p.H106Q | Missense Mutation (SNP) | VAF 44/48 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SHOC1 | c.1138C>G p.L380V | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- SKIDA1 | c.1897G>C p.E633Q | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC16A2 | c.1375A>G p.M459V | Missense Mutation (SNP) | VAF 17/17 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- SLC35A4 | c.722C>G p.S241C | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- SMAP1 | c.790-3C>T | Splice Region (SNP) | VAF 120/236 reads (51%) | called by muse, mutect2, varscan2
- SMC4 | c.3004G>C p.E1002Q | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SNRNP200 | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- SNRNP40 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SPATA18 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- SPATA31D1 | c.2378C>T p.S793L | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- SRRT | c.1417G>A p.V473I | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- SRRT | c.1549G>T p.V517L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SSR4 | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 73/74 reads (99%) | SIFT tolerated (0.49); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TLR2 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 48/102 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.093); called by muse, mutect2
- TNK2 | c.2407C>A p.L803M | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- TPR | c.5602G>A p.E1868K | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TRBJ2-4 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 36/111 reads (32%) | called by muse, mutect2, varscan2
- TSGA10 | c.1811dup p.N604Kfs*2 | Frame Shift Ins (INS) | VAF 7/20 reads (35%) | called by mutect2, pindel, varscan2
- USP43 | c.336G>A p.M112I | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- WDR13 | c.1309G>C p.D437H | Missense Mutation (SNP) | VAF 21/22 reads (95%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WNK3 | c.2974G>C p.E992Q | Missense Mutation (SNP) | VAF 58/62 reads (94%) | SIFT tolerated (0.1); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- ZBTB42 | c.55G>C p.E19Q | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.449); called by muse, mutect2
- ZNF569 | c.1714C>G p.H572D | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZRANB3 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 55/104 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ACSS1 | c.1449G>A p.E483= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs932586269; called by muse, mutect2, varscan2
- ANKMY1 | c.1029C>T p.F343= | Silent (SNP) | VAF 57/106 reads (54%) | catalogued as rs866522532; called by muse, mutect2, varscan2
- ANO8 | c.357C>T p.L119= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs763093507; called by muse, varscan2
- AP3B1 | c.1329C>T p.L443= | Silent (SNP) | VAF 92/187 reads (49%) | called by muse, mutect2, varscan2
- ARSJ | c.1638C>T p.L546= | Silent (SNP) | VAF 34/72 reads (47%) | called by muse, mutect2, varscan2
- ATP4B | c.567C>T p.F189= | Silent (SNP) | VAF 25/26 reads (96%) | called by muse, mutect2, varscan2
- CACHD1 | c.2979C>T p.N993= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs1282886102; called by muse, mutect2, varscan2
- CDC14C | c.1596C>A p.T532= (on ENST00000428251; = p.T425= on NM_152627.3) | Silent (SNP) | VAF 29/287 reads (10%) | catalogued as rs1172697193; called by muse, mutect2
- CDON | c.1425C>T p.F475= | Silent (SNP) | VAF 62/139 reads (45%) | catalogued as rs768862954, COSV54995704; called by muse, mutect2, varscan2
- CEACAM5 | c.600C>A p.L200= | Silent (SNP) | VAF 57/143 reads (40%) | called by muse, mutect2, varscan2
- CEP72 | c.1713G>A p.L571= | Silent (SNP) | VAF 20/39 reads (51%) | called by muse, mutect2, varscan2
- CNNM2 | c.2286C>T p.L762= | Silent (SNP) | VAF 60/132 reads (45%) | catalogued as rs201183107, COSV100881925; called by muse, mutect2, varscan2
- CPXM1 | c.87C>T p.L29= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs1355542940; called by muse, mutect2, varscan2
- DEDD | c.180C>A p.L60= | Silent (SNP) | VAF 138/726 reads (19%) | catalogued as COSV63502712; called by mutect2, varscan2
- DNAH2 | c.12483G>A p.V4161= | Silent (SNP) | VAF 29/58 reads (50%) | called by muse, mutect2, varscan2
- DUSP11 | c.753C>T p.I251= | Silent (SNP) | VAF 65/137 reads (47%) | catalogued as rs1353696929; called by muse, mutect2, varscan2
- DUSP23 | c.183G>A p.L61= | Silent (SNP) | VAF 46/84 reads (55%) | called by muse, mutect2, varscan2
- ENG | c.57C>T p.L19= | Silent (SNP) | VAF 35/113 reads (31%) | called by muse, mutect2, varscan2
- EOMES | c.93G>A p.G31= | Silent (SNP) | VAF 25/114 reads (22%) | called by muse, varscan2
- EPHA4 | c.2466G>A p.E822= | Silent (SNP) | VAF 45/100 reads (45%) | called by muse, mutect2, varscan2
- EPS8L2 | c.705C>T p.F235= | Silent (SNP) | VAF 12/17 reads (71%) | catalogued as rs1472710515; called by muse, mutect2, varscan2
- FBLIM1 | c.1032C>G p.V344= | Silent (SNP) | VAF 108/284 reads (38%) | called by muse, mutect2, varscan2
- FCHSD1 | c.1719C>T p.I573= | Silent (SNP) | VAF 66/159 reads (42%) | called by muse, mutect2, varscan2
- FLCN | c.429C>T p.F143= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as rs773792624, CD123427, COSV53257333, COSV53264270; ClinVar: likely benign; called by muse, mutect2, varscan2
- FMN1 | c.3234C>T p.F1078= (on ENST00000616417 / NM_001277313.2; = p.F855= on NM_001103184.4) | Silent (SNP) | VAF 50/104 reads (48%) | catalogued as rs865986556, COSV100569259; called by muse, varscan2
- FN1 | c.4144C>A p.R1382= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as CD164418; called by muse, mutect2, varscan2
- GCC1 | c.1509C>T p.L503= | Silent (SNP) | VAF 32/84 reads (38%) | called by muse, mutect2, varscan2
- GOLGA3 | c.2640G>A p.L880= | Silent (SNP) | VAF 22/37 reads (59%) | catalogued as rs1566090958; called by muse, mutect2, varscan2
- GPIHBP1 | c.243G>A p.Q81= | Silent (SNP) | VAF 70/110 reads (64%) | catalogued as rs1191147691; called by muse, mutect2, varscan2
- GRK5 | c.1176G>A p.V392= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs200876105; called by muse, mutect2, varscan2
- H4-16 | c.195C>T p.N65= | Silent (SNP) | VAF 50/116 reads (43%) | catalogued as rs1200037531; called by muse, mutect2, varscan2
- IGLV4-69 | c.231C>T p.S77= | Silent (SNP) | VAF 54/98 reads (55%) | catalogued as rs768196983; called by muse, varscan2
- IPO9 | c.2985G>A p.L995= | Silent (SNP) | VAF 104/200 reads (52%) | called by muse, mutect2, varscan2
- KCNH7 | c.825G>A p.S275= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as rs369255891; called by muse, mutect2, varscan2
- KIAA0319L | c.3115C>T p.L1039= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs780034518; called by muse, mutect2, varscan2
- KRTAP13-3 | c.201G>A p.Q67= | Silent (SNP) | VAF 30/63 reads (48%) | called by muse, mutect2, varscan2
- MAGI1 | c.270C>T p.I90= | Silent (SNP) | VAF 77/212 reads (36%) | called by muse, mutect2, varscan2
- MAP2K7 | c.1027C>T p.L343= | Silent (SNP) | VAF 30/47 reads (64%) | called by muse, mutect2, varscan2
- MBOAT1 | c.156C>T p.I52= | Silent (SNP) | VAF 44/107 reads (41%) | called by muse, mutect2, varscan2
- MKI67 | c.8553G>C p.V2851= | Silent (SNP) | VAF 61/110 reads (55%) | called by muse, mutect2, varscan2
- MYBPHL | c.111C>T p.G37= | Silent (SNP) | VAF 28/54 reads (52%) | catalogued as rs761925053; called by muse, mutect2, varscan2
- NDC80 | c.888G>A p.L296= | Silent (SNP) | VAF 38/138 reads (28%) | catalogued as COSV99859995; called by muse, mutect2, varscan2
- NHS | c.3768C>T p.V1256= | Silent (SNP) | VAF 52/53 reads (98%) | called by muse, mutect2, varscan2
- NPHP1 | c.1128G>A p.S376= (on ENST00000393272 / NM_207181.4; = p.S377= on NM_000272.5) | Silent (SNP) | VAF 50/110 reads (45%) | catalogued as rs533125951, COSV100337819; ClinVar: likely benign; called by muse, mutect2, varscan2
- NUDT1 | c.195A>G p.G65= (on ENST00000397048 / NM_198952.1; = p.G42= on NM_002452.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- OSBPL11 | c.1699C>T p.L567= | Silent (SNP) | VAF 81/236 reads (34%) | catalogued as COSV99953918; called by muse, mutect2, varscan2
- OTOGL | c.1527C>T p.L509= (on ENST00000547103; = p.L500= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as rs780285450, COSV72007331; called by muse, mutect2, varscan2
- PCDHB8 | c.1107C>T p.F369= | Silent (SNP) | VAF 26/92 reads (28%) | called by muse, mutect2, varscan2
- PEX14 | c.1038G>A p.Q346= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV100749957, COSV63059716; called by muse, mutect2
- PGM1 | c.111G>A p.E37= | Silent (SNP) | VAF 58/99 reads (59%) | catalogued as rs1266630709; called by muse, mutect2, varscan2
- PI15 | c.153G>A p.A51= | Silent (SNP) | VAF 109/193 reads (56%) | catalogued as rs1337047728, COSV52642702; called by muse, mutect2, varscan2
- PIGQ | c.1410C>T p.F470= | Silent (SNP) | VAF 58/118 reads (49%) | called by muse, mutect2, varscan2
- PTCHD3 | c.153G>A p.P51= | Silent (SNP) | VAF 73/136 reads (54%) | catalogued as rs1386975242, COSV71256764, COSV71257170; called by muse, mutect2, varscan2
- RAB3GAP2 | c.3763C>T p.L1255= | Silent (SNP) | VAF 16/117 reads (14%) | called by muse, mutect2, varscan2
- RTP2 | c.360C>T p.N120= | Silent (SNP) | VAF 37/114 reads (32%) | called by muse, mutect2, varscan2
- RUSC2 | c.2592C>T p.L864= | Silent (SNP) | VAF 12/54 reads (22%) | called by muse, mutect2, varscan2
- SAA2 | c.225G>C p.V75= | Silent (SNP) | VAF 52/214 reads (24%) | called by muse, mutect2, varscan2
- SERPINB10 | c.45G>A p.L15= | Silent (SNP) | VAF 87/301 reads (29%) | called by muse, mutect2, varscan2
- SETD3 | c.465C>A p.I155= | Silent (SNP) | VAF 11/113 reads (10%) | catalogued as COSV59284878, COSV59286190; called by muse, mutect2
- SHLD2 | c.2052G>A p.L684= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as COSV53954270; called by muse, mutect2, varscan2
- STRADA | c.474C>T p.L158= (on ENST00000336174 / NM_001363786.1; = p.L121= on NM_153335.6) | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as rs1216233231, COSV55563595; called by muse, mutect2, varscan2
- TBL1X | c.906C>T p.L302= | Silent (SNP) | VAF 47/55 reads (85%) | called by muse, mutect2, varscan2
- TBXAS1 | c.1413C>T p.P471= | Silent (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2, varscan2
- TINF2 | c.1020G>A p.L340= | Silent (SNP) | VAF 181/383 reads (47%) | called by muse, mutect2, varscan2
- TMEM132B | c.3132C>T p.I1044= | Silent (SNP) | VAF 34/77 reads (44%) | catalogued as COSV54751502; called by muse, mutect2, varscan2
- TRAV8-7 | c.300G>A p.V100= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as rs1425470219; called by muse, mutect2, varscan2
- TRIM32 | c.888G>A p.K296= | Silent (SNP) | VAF 13/45 reads (29%) | called by muse, mutect2, varscan2
- TSC22D2 | c.981G>A p.T327= | Silent (SNP) | VAF 35/98 reads (36%) | called by muse, mutect2, varscan2
- TTN | c.100068C>A p.L33356= (on ENST00000591111; = p.L25932= on NM_003319.4) | Silent (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- UMOD | c.1251C>T p.L417= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as rs1412107982; called by muse, mutect2, varscan2
- WASHC4 | c.12G>A p.E4= | Silent (SNP) | VAF 26/63 reads (41%) | called by muse, mutect2, varscan2
- ZNF160 | c.1638C>T p.F546= | Silent (SNP) | VAF 60/136 reads (44%) | called by muse, varscan2
- ZNF17 | c.51C>T p.F17= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as COSV100299988, COSV56922736; called by muse, mutect2, varscan2
- ZNF532 | c.2742C>T p.F914= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV60171996; called by muse, mutect2, varscan2
- AC004899.2 | chr7:48846489 G>T | 5'Flank (SNP) | VAF 27/109 reads (25%) | called by muse, mutect2, varscan2
- AC018755.3 | n.612C>T | RNA (SNP) | VAF 32/69 reads (46%) | called by muse, mutect2, varscan2
- AC083864.1 | n.911C>T | RNA (SNP) | VAF 60/102 reads (59%) | called by muse, mutect2
- ACACB | c.*1712G>A | 3'UTR (SNP) | VAF 33/82 reads (40%) | called by muse, mutect2, varscan2
- ADGRG7 | c.-173C>T | 5'UTR (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- AGBL4 | c.1267+2236G>A | Intron (SNP) | VAF 15/43 reads (35%) | called by muse, mutect2, varscan2
- AGR2 | c.140-120C>T | Intron (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- AICDA | c.*882C>T | 3'UTR (SNP) | VAF 31/67 reads (46%) | called by muse, mutect2, varscan2
- ALX4 | c.*1085G>C | 3'UTR (SNP) | VAF 50/100 reads (50%) | called by muse, mutect2, varscan2
- AMIGO1 | chr1:109506433 G>C | 3'Flank (SNP) | VAF 28/72 reads (39%) | called by muse, mutect2, varscan2
- ANKDD1A | c.1065+29C>T | Intron (SNP) | VAF 26/54 reads (48%) | called by muse, mutect2, varscan2
- AP1G2 | c.-60G>A | 5'UTR (SNP) | VAF 16/33 reads (48%) | catalogued as rs979322732, COSV58113041; called by muse, mutect2, varscan2
- ARL5B | c.-32G>A | 5'UTR (SNP) | VAF 29/57 reads (51%) | catalogued as rs763293879, COSV66011366; called by muse, mutect2, varscan2
- AS3MT | c.*119C>G | 3'UTR (SNP) | VAF 83/159 reads (52%) | catalogued as rs1351298555, COSV100185661; called by muse, mutect2, varscan2
- ASCL4 | c.-622G>A | 5'UTR (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- ASPH | c.253+86G>A | Intron (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2
- ASXL1 | c.57+481G>A | Intron (SNP) | VAF 23/53 reads (43%) | called by muse, mutect2, varscan2
- B3GALT5-AS1 | n.781C>A | RNA (SNP) | VAF 98/207 reads (47%) | called by muse, mutect2, varscan2
- BAP1 | c.1891-84C>T | Intron (SNP) | VAF 25/79 reads (32%) | called by muse, mutect2, varscan2
- BBX | c.*1246G>A | 3'UTR (SNP) | VAF 32/88 reads (36%) | called by muse, mutect2, varscan2
- BCL9L | c.*2770G>C | 3'UTR (SNP) | VAF 42/127 reads (33%) | called by muse, mutect2, varscan2
- BDH1 | c.*1530C>T | 3'UTR (SNP) | VAF 36/124 reads (29%) | catalogued as rs922739311; called by muse, mutect2, varscan2
- BDNF | c.-21-347T>G | Intron (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- BNIP2 | c.*1330G>A | 3'UTR (SNP) | VAF 19/46 reads (41%) | called by muse, mutect2, varscan2
- BRF1 | c.789-697C>T | Intron (SNP) | VAF 46/138 reads (33%) | called by muse, mutect2
- BTN3A1 | c.937+22G>C | Intron (SNP) | VAF 61/128 reads (48%) | called by muse, mutect2, varscan2
- C14orf132 | chr14:96087497 C>T | 3'Flank (SNP) | VAF 32/56 reads (57%) | catalogued as rs1005082533; called by muse, mutect2, varscan2
- C1QTNF6 | c.*1952G>A | 3'UTR (SNP) | VAF 32/67 reads (48%) | called by muse, mutect2, varscan2
- C1orf21 | c.*3026G>A | 3'UTR (SNP) | VAF 71/182 reads (39%) | called by muse, mutect2, varscan2
- C4orf3 | chr4:119300650 C>T | 5'Flank (SNP) | VAF 87/184 reads (47%) | called by muse, mutect2, varscan2
- C8orf34 | c.*750A>C | 3'UTR (SNP) | VAF 41/74 reads (55%) | called by muse, mutect2, varscan2
- C8orf82 | c.*468G>T | 3'UTR (SNP) | VAF 52/84 reads (62%) | called by muse, mutect2, varscan2
- CA3 | c.*174C>T | 3'UTR (SNP) | VAF 30/60 reads (50%) | catalogued as rs978750634; called by muse, mutect2, varscan2
- CALM1 | c.*783C>T | 3'UTR (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2, varscan2
- CAPN8 | c.307+11570G>T | Intron (SNP) | VAF 54/383 reads (14%) | called by muse, mutect2, varscan2
- CCDC142 | c.1021+55T>A | Intron (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- CCS | chr11:66593160 G>T | 5'Flank (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- CDCA2 | c.*16G>A | 3'UTR (SNP) | VAF 20/22 reads (91%) | called by muse, mutect2, varscan2
- CELSR3 | c.*1215del | 3'UTR (DEL) | VAF 16/67 reads (24%) | called by mutect2, pindel, varscan2
- CEP78 | c.*7052C>T | 3'UTR (SNP) | VAF 33/112 reads (29%) | catalogued as COSV70005472; called by muse, mutect2, varscan2
- CFAP44 | c.5373+648G>A | Intron (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- CHD2 | c.*985C>T | 3'UTR (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2, varscan2
- CHUK | c.-52G>A | 5'UTR (SNP) | VAF 15/22 reads (68%) | catalogued as rs1451481516; called by muse, mutect2, varscan2
- CLEC12B | c.680+399C>T | Intron (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- CLEC2D | c.*251A>C | 3'UTR (SNP) | VAF 24/46 reads (52%) | called by muse, varscan2
- CNTN1 | c.*426G>A | 3'UTR (SNP) | VAF 30/72 reads (42%) | called by muse, mutect2, varscan2
- CNTNAP3B | c.1072-2012C>T | Intron (SNP) | VAF 29/97 reads (30%) | called by muse, mutect2, varscan2
- COL12A1 | c.*2076C>T | 3'UTR (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- COL18A1 | c.4462-45C>G | Intron (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- COL4A4 | c.*4469C>G | 3'UTR (SNP) | VAF 39/81 reads (48%) | called by muse, mutect2, varscan2
- COQ4 | chr9:128322838 C>T | 5'Flank (SNP) | VAF 38/139 reads (27%) | catalogued as rs773112331; called by muse, mutect2, varscan2
- CRISPLD2 | c.*2599G>A | 3'UTR (SNP) | VAF 28/34 reads (82%) | catalogued as rs1295108058; called by muse, mutect2, varscan2
- CROT | c.240+221C>T | Intron (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- CXXC1 | c.1414-17C>T | Intron (SNP) | VAF 52/217 reads (24%) | catalogued as rs1399778885; called by muse, mutect2, varscan2
- CYFIP2 | c.3282+947G>A | Intron (SNP) | VAF 44/111 reads (40%) | called by muse, mutect2, varscan2
- CYHR1 | chr8:144465423 C>T | 5'Flank (SNP) | VAF 10/22 reads (45%) | called by muse, mutect2, varscan2
- CYP2D6 | c.180+29G>C | Intron (SNP) | VAF 11/13 reads (85%) | called by muse, mutect2, varscan2
- DALRD3 | chr3:49022270 G>A | 5'Flank (SNP) | VAF 54/164 reads (33%) | catalogued as rs755982046; called by muse, mutect2, varscan2
- DCC | c.*1455G>A | 3'UTR (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- DDX51 | c.*1733G>A | 3'UTR (SNP) | VAF 27/81 reads (33%) | called by muse, mutect2, varscan2
- DENND6B | c.759-21G>A | Intron (SNP) | VAF 8/12 reads (67%) | catalogued as rs772692744; called by muse, mutect2
- DERL2 | chr17:5486194 C>T | 5'Flank (SNP) | VAF 27/52 reads (52%) | called by muse, mutect2, varscan2
- DESI2 | c.-84G>A | 5'UTR (SNP) | VAF 50/50 reads (100%) | called by muse, mutect2, varscan2
- DIABLO | c.97-12C>T | Intron (SNP) | VAF 44/92 reads (48%) | called by muse, mutect2, varscan2
- DLX2 | c.*371G>A | 3'UTR (SNP) | VAF 11/32 reads (34%) | catalogued as rs1346761551; called by muse, mutect2, varscan2
- DNAJB2 | c.352+69G>A | Intron (SNP) | VAF 44/108 reads (41%) | called by muse, mutect2, varscan2
- DNER | c.1610-27C>A | Intron (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- DNMT1 | c.844-63C>T | Intron (SNP) | VAF 28/77 reads (36%) | catalogued as rs1032332041; called by muse, mutect2, varscan2
- DPPA4 | c.*608T>A | 3'UTR (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- DRAM1 | c.-1G>T | 5'UTR (SNP) | VAF 29/60 reads (48%) | called by muse, mutect2, varscan2
- DUT | chr15:48331277 G>C | 5'Flank (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2, varscan2
- EDEM1 | c.*2107C>T | 3'UTR (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2, varscan2
- EIF3G | c.68-120C>T | Intron (SNP) | VAF 48/93 reads (52%) | catalogued as rs572125927; called by muse, mutect2, varscan2
- EIF3J | c.-27C>T | 5'UTR (SNP) | VAF 64/125 reads (51%) | catalogued as COSV99970589; called by muse, mutect2, varscan2
- EIF4E | c.19-7795G>A | Intron (SNP) | VAF 20/43 reads (47%) | called by muse, varscan2
- EPB41L2 | c.1834-253G>A | Intron (SNP) | VAF 99/191 reads (52%) | called by muse, varscan2
- ERAP2 | c.2739+29C>T | Intron (SNP) | VAF 45/108 reads (42%) | called by muse, mutect2, varscan2
- ERICH1 | c.1258+1896C>T | Intron (SNP) | VAF 96/222 reads (43%) | called by muse, mutect2, varscan2
- ERMN | c.*884C>G | 3'UTR (SNP) | VAF 15/36 reads (42%) | called by muse, mutect2, varscan2
- EVI2A | c.*64T>C | 3'UTR (SNP) | VAF 10/25 reads (40%) | called by mutect2, varscan2
- F2RL1 | c.*210C>T | 3'UTR (SNP) | VAF 24/89 reads (27%) | called by muse, mutect2, varscan2
- FAM117B | c.*2337G>C | 3'UTR (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- FAM160A1 | c.-104G>A | 5'UTR (SNP) | VAF 101/199 reads (51%) | called by muse, mutect2, varscan2
- FAM166C | c.-12C>G | 5'UTR (SNP) | VAF 50/98 reads (51%) | catalogued as COSV55518171; called by muse, mutect2, varscan2
- FAM205BP | n.782G>C | RNA (SNP) | VAF 88/283 reads (31%) | called by muse, mutect2, varscan2
- FAM234B | c.*730C>T | 3'UTR (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
- FARS2 | c.904+513G>A | Intron (SNP) | VAF 155/366 reads (42%) | called by muse, mutect2, varscan2
- FAS | c.*1406C>G | 3'UTR (SNP) | VAF 56/111 reads (50%) | catalogued as rs1000812226; called by muse, mutect2, varscan2
- FCMR | c.*389C>T | 3'UTR (SNP) | VAF 74/242 reads (31%) | catalogued as rs959229089; called by muse, varscan2
- FGF2 | c.*1825C>T | 3'UTR (SNP) | VAF 13/20 reads (65%) | called by muse, mutect2, varscan2
- FLI1 | c.*13C>T | 3'UTR (SNP) | VAF 135/298 reads (45%) | called by muse, mutect2, varscan2
- FNBP1 | c.*317C>A | 3'UTR (SNP) | VAF 123/190 reads (65%) | called by muse, mutect2, varscan2
- FOXP2 | c.*2356G>A | 3'UTR (SNP) | VAF 43/64 reads (67%) | called by muse, mutect2, varscan2
- FREM2 | c.*1647C>G | 3'UTR (SNP) | VAF 24/26 reads (92%) | called by muse, mutect2, varscan2
- GABRQ | c.*3781C>T | 3'UTR (SNP) | VAF 18/18 reads (100%) | catalogued as rs1223817965; called by muse, mutect2, varscan2
- GAD1 | c.639-1441G>A | Intron (SNP) | VAF 97/217 reads (45%) | called by muse, mutect2, varscan2
- GALT | c.1059+68C>T | Intron (SNP) | VAF 20/54 reads (37%) | called by muse, mutect2
- GAREM1 | c.*4122G>A | 3'UTR (SNP) | VAF 22/115 reads (19%) | called by muse, mutect2, varscan2
- GBP2 | c.*162G>C | 3'UTR (SNP) | VAF 35/84 reads (42%) | called by muse, mutect2, varscan2
- GCH1 | c.-142C>T | 5'UTR (SNP) | VAF 56/114 reads (49%) | catalogued as rs777475712; called by muse, mutect2, varscan2
- GFAP | c.1377+170C>G | Intron (SNP) | VAF 24/50 reads (48%) | called by muse, varscan2
- GPM6A | c.*129C>T | 3'UTR (SNP) | VAF 35/72 reads (49%) | called by muse, mutect2, varscan2
- GPR135 | c.*438G>A | 3'UTR (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- GRIN3A | c.*3529C>T | 3'UTR (SNP) | VAF 14/77 reads (18%) | called by muse, mutect2, varscan2
- GRM5 | c.662-61869C>G | Intron (SNP) | VAF 50/109 reads (46%) | called by muse, mutect2, varscan2
- GUF1 | c.*1574G>A | 3'UTR (SNP) | VAF 31/76 reads (41%) | catalogued as rs192367936; called by muse, mutect2, varscan2
- H2AX | c.*392G>A | 3'UTR (SNP) | VAF 25/64 reads (39%) | called by muse, mutect2, varscan2
- HDAC2 | c.*166G>T | 3'UTR (SNP) | VAF 23/43 reads (53%) | called by muse, mutect2, varscan2
- HECTD2 | c.1094+42A>G | Intron (SNP) | VAF 43/81 reads (53%) | called by muse, mutect2, varscan2
- HEPACAM | c.*847G>A | 3'UTR (SNP) | VAF 54/119 reads (45%) | called by muse, mutect2, varscan2
- HID1 | c.*747G>T | 3'UTR (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
- HJURP | chr2:233854545 C>G | 5'Flank (SNP) | VAF 93/171 reads (54%) | catalogued as COSV101366443; called by muse, varscan2
- HOXB3 | chr17:48545260 G>C | 3'Flank (SNP) | VAF 39/85 reads (46%) | called by muse, mutect2, varscan2
- HOXD11 | c.*281G>T | 3'UTR (SNP) | VAF 27/58 reads (47%) | called by muse, mutect2, varscan2
- HSPA4L | chr4:127782044 G>A | 5'Flank (SNP) | VAF 43/98 reads (44%) | called by muse, mutect2, varscan2
- HTR1A | c.-165C>T | 5'UTR (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- HYDIN2 | n.5097G>A | RNA (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2
- IDI1 | c.-54G>A | 5'UTR (SNP) | VAF 39/72 reads (54%) | called by muse, mutect2, varscan2
- IFIH1 | chr2:162319106 G>A | 5'Flank (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- IHH | c.*538C>T | 3'UTR (SNP) | VAF 52/128 reads (41%) | called by muse, mutect2, varscan2
- IKZF1 | c.*891C>T | 3'UTR (SNP) | VAF 50/156 reads (32%) | called by muse, mutect2, varscan2
- IL17RD | c.*399C>T | 3'UTR (SNP) | VAF 12/62 reads (19%) | called by muse, mutect2, varscan2
- IL3 | c.*40G>A | 3'UTR (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- INPP5F | c.*408C>T | 3'UTR (SNP) | VAF 8/19 reads (42%) | called by muse, mutect2, varscan2
- IRF6 | c.*621G>A | 3'UTR (SNP) | VAF 60/151 reads (40%) | catalogued as rs1242546837; called by muse, mutect2, varscan2
- ISL1 | c.219-1001C>T | Intron (SNP) | VAF 65/126 reads (52%) | called by muse, mutect2, varscan2
- JAK3 | c.567-33G>A | Intron (SNP) | VAF 23/42 reads (55%) | called by muse, mutect2, varscan2
- KANK1 | c.3246-810G>A | Intron (SNP) | VAF 7/29 reads (24%) | called by muse, mutect2
- KCNJ6 | c.*268C>T | 3'UTR (SNP) | VAF 21/44 reads (48%) | called by muse, mutect2, varscan2
- KDM4A | c.*600C>T | 3'UTR (SNP) | VAF 27/55 reads (49%) | catalogued as rs1211997374; called by muse, mutect2, varscan2
- KHNYN | c.*442G>A | 3'UTR (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- KIF6 | c.*6251C>T | 3'UTR (SNP) | VAF 67/142 reads (47%) | called by muse, mutect2
- KLHDC8B | c.-109C>G | 5'UTR (SNP) | VAF 27/98 reads (28%) | called by muse, mutect2, varscan2
- KLHL6 | c.*4132G>C | 3'UTR (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- KLHL6 | c.*532C>T | 3'UTR (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- KMT2A | c.432+12774G>A | Intron (SNP) | VAF 28/58 reads (48%) | called by muse, mutect2, varscan2
- KREMEN2 | c.-28G>A | 5'UTR (SNP) | VAF 94/199 reads (47%) | catalogued as rs368338199; called by muse, mutect2, varscan2
- KRTAP4-6 | c.*83G>A | 3'UTR (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2, varscan2
- LCN6 | c.301+39C>T | Intron (SNP) | VAF 66/204 reads (32%) | catalogued as rs1319631933; called by muse, mutect2, varscan2
- LIFR | c.*4158C>T | 3'UTR (SNP) | VAF 32/70 reads (46%) | catalogued as rs1477280293; called by muse, mutect2, varscan2
- LILRB5 | c.*248A>T | 3'UTR (SNP) | VAF 19/37 reads (51%) | called by muse, mutect2, varscan2
- LINC02396 | n.205G>C | RNA (SNP) | VAF 28/78 reads (36%) | called by muse, mutect2, varscan2
- LMNB1 | c.-28C>T | 5'UTR (SNP) | VAF 10/16 reads (63%) | catalogued as rs1231218853; called by muse, mutect2, varscan2
- LSM14B | c.*324G>C | 3'UTR (SNP) | VAF 14/44 reads (32%) | called by mutect2, varscan2
- LURAP1L | c.-454C>T | 5'UTR (SNP) | VAF 28/86 reads (33%) | called by muse, mutect2, varscan2
- LXN | c.*116G>A | 3'UTR (SNP) | VAF 86/255 reads (34%) | called by muse, mutect2, varscan2
- LY9 | c.454+2524G>A | Intron (SNP) | VAF 10/10 reads (100%) | catalogued as rs572469956; called by muse, varscan2
- LZTS1 | c.*3197G>A | 3'UTR (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- MAFB | c.-10C>T | 5'UTR (SNP) | VAF 40/75 reads (53%) | catalogued as rs1465347933, COSV100965079; called by muse, mutect2, varscan2
- MAGI1 | c.3634+360C>T | Intron (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- MALT1 | c.*2351G>A | 3'UTR (SNP) | VAF 25/87 reads (29%) | called by muse, mutect2, varscan2
- MAP1B | chr5:72107236 G>A | 5'Flank (SNP) | VAF 18/35 reads (51%) | called by muse, mutect2, varscan2
- MASP2 | c.544+427C>T | Intron (SNP) | VAF 16/31 reads (52%) | catalogued as rs770083587; called by muse, mutect2, varscan2
- MATN2 | c.*284C>T | 3'UTR (SNP) | VAF 38/95 reads (40%) | called by muse, mutect2, varscan2
- MED1 | c.739+77C>T | Intron (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- MED12 | c.2542-56C>T | Intron (SNP) | VAF 22/23 reads (96%) | called by muse, mutect2, varscan2
- MFSD8 | c.*2209C>T | 3'UTR (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- MIEF1 | c.*1512C>T | 3'UTR (SNP) | VAF 29/70 reads (41%) | called by muse, mutect2, varscan2
- MMS22L | c.*3784C>T | 3'UTR (SNP) | VAF 32/63 reads (51%) | called by muse, mutect2, varscan2
- MOXD1 | c.264+10510C>T | Intron (SNP) | VAF 37/84 reads (44%) | called by muse, mutect2, varscan2
- MSL2 | c.*2201C>T | 3'UTR (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- MTFR2 | c.63+43C>T | Intron (SNP) | VAF 34/70 reads (49%) | catalogued as rs370837157; called by muse, mutect2, varscan2
- MTHFR | c.-13-590C>T | Intron (SNP) | VAF 18/24 reads (75%) | called by muse, mutect2, varscan2
- MUC22 | c.-198C>T | 5'UTR (SNP) | VAF 4/10 reads (40%) | called by muse, mutect2
- MYO15A | c.8089-18G>A | Intron (SNP) | VAF 22/43 reads (51%) | called by muse, mutect2, varscan2
- MYO1C | c.*85C>T | 3'UTR (SNP) | VAF 57/119 reads (48%) | called by muse, mutect2, varscan2
- NDST1 | c.*4642C>A | 3'UTR (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- NDUFAB1 | c.*8+153G>A | Intron (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2
- NDUFB6 | chr9:32573184 C>A | 5'Flank (SNP) | VAF 127/210 reads (60%) | called by muse, mutect2, varscan2
- NIPAL1 | c.*453C>T | 3'UTR (SNP) | VAF 5/13 reads (38%) | catalogued as rs1472440286; called by muse, mutect2, varscan2
- NIPAL3 | c.637+897C>T | Intron (SNP) | VAF 8/17 reads (47%) | called by mutect2, varscan2
- NLN | c.*5307G>A | 3'UTR (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- NPHP3 | c.*80A>G | 3'UTR (SNP) | VAF 33/106 reads (31%) | catalogued as COSV53905427; called by muse, mutect2, varscan2
- NT5DC1 | c.*1614T>C | 3'UTR (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- OAS2 | c.*261dup | 3'UTR (INS) | VAF 19/60 reads (32%) | called by mutect2, pindel, varscan2
- OGA | c.-374C>T | 5'UTR (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- OPRK1 | c.*1928C>T | 3'UTR (SNP) | VAF 36/76 reads (47%) | catalogued as rs1050530669; called by muse, mutect2, varscan2
- P3H2 | c.*708C>T | 3'UTR (SNP) | VAF 47/118 reads (40%) | called by muse, mutect2, varscan2
- PACS2 | c.1989-113G>A | Intron (SNP) | VAF 8/10 reads (80%) | catalogued as rs1181789108; called by muse, mutect2
- PARP2 | c.-8C>G | 5'UTR (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- PAWR | c.*2075C>T | 3'UTR (SNP) | VAF 11/19 reads (58%) | called by muse, mutect2, varscan2
- PBX1 | c.*101G>A | 3'UTR (SNP) | VAF 96/99 reads (97%) | catalogued as rs1440357469; called by muse, mutect2, varscan2
- PDE4DIP | c.637-8601G>A | Intron (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- PHF20L1 | c.*1023C>T | 3'UTR (SNP) | VAF 33/53 reads (62%) | called by muse, mutect2, varscan2
- PLA2R1 | c.*406G>A | 3'UTR (SNP) | VAF 24/57 reads (42%) | catalogued as rs1220442215; called by muse, mutect2, varscan2
- PNLIPRP2 | c.49+17C>T | Intron (SNP) | VAF 32/87 reads (37%) | called by muse, mutect2, varscan2
- PNPLA7 | c.3570+45C>T | Intron (SNP) | VAF 42/125 reads (34%) | called by muse, mutect2, varscan2
- POLM | c.969-82G>A | Intron (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- POLM | c.-26C>G | 5'UTR (SNP) | VAF 70/108 reads (65%) | called by muse, mutect2, varscan2
- POLR1H | chr6:30061243 C>G | 5'Flank (SNP) | VAF 44/82 reads (54%) | called by muse, mutect2, varscan2
- PPCDC | c.136-127_136-124dup | Intron (INS) | VAF 8/46 reads (17%) | called by mutect2, pindel, varscan2
- PPM1L | c.*8382del | 3'UTR (DEL) | VAF 12/70 reads (17%) | called by pindel, varscan2
- PPM1M | c.*1212G>A | 3'UTR (SNP) | VAF 47/68 reads (69%) | catalogued as COSV56598703; called by muse, mutect2, varscan2
- PRKAA2 | c.*4299C>T | 3'UTR (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- PROK2 | c.*167C>T | 3'UTR (SNP) | VAF 22/68 reads (32%) | catalogued as rs549270901; called by mutect2, varscan2
- PTPN21 | c.932+3468G>A | Intron (SNP) | VAF 15/45 reads (33%) | catalogued as rs1463775965; called by muse, mutect2
- PURA | c.-54G>A | 5'UTR (SNP) | VAF 7/17 reads (41%) | called by muse, mutect2, varscan2
- QDPR | c.*561C>T | 3'UTR (SNP) | VAF 44/101 reads (44%) | called by muse, mutect2, varscan2
- RAB10 | c.-114T>C | 5'UTR (SNP) | VAF 24/41 reads (59%) | called by muse, mutect2, varscan2
- RARS2 | c.-9G>A | 5'UTR (SNP) | VAF 49/111 reads (44%) | catalogued as rs773928698; called by muse, mutect2, varscan2
- RASGRF1 | c.-216G>A | 5'UTR (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- RBFA | c.*2886G>A | 3'UTR (SNP) | VAF 28/100 reads (28%) | called by muse, varscan2
- RBM45 | c.-75G>A | 5'UTR (SNP) | VAF 28/88 reads (32%) | called by muse, mutect2, varscan2
- RCOR1 | c.*3226C>G | 3'UTR (SNP) | VAF 18/41 reads (44%) | called by muse, mutect2, varscan2
- RHBDL2 | c.-35C>A | 5'UTR (SNP) | VAF 73/150 reads (49%) | called by muse, mutect2, varscan2
- RHD | c.*1286G>A | 3'UTR (SNP) | VAF 77/81 reads (95%) | called by muse, mutect2, varscan2
- RPL35 | c.3+29G>A | Intron (SNP) | VAF 61/168 reads (36%) | called by muse, mutect2, varscan2
- RPLP0 | c.54+150A>T | Intron (SNP) | VAF 7/16 reads (44%) | called by muse, mutect2
- RPS18 | c.3+89G>A | Intron (SNP) | VAF 77/171 reads (45%) | called by muse, mutect2, varscan2
- RRP15 | c.*1848A>T | 3'UTR (SNP) | VAF 35/73 reads (48%) | called by muse, mutect2, varscan2
- SCLY | c.113+189G>A | Intron (SNP) | VAF 57/115 reads (50%) | called by muse, mutect2, varscan2
- SDCBP | c.-15-4277C>T | Intron (SNP) | VAF 32/71 reads (45%) | catalogued as COSV52707327; called by muse, mutect2, varscan2
- SDK1 | c.*118G>A | 3'UTR (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- SEBOX | c.-26C>T | 5'UTR (SNP) | VAF 74/139 reads (53%) | catalogued as rs781849455; called by muse, mutect2, varscan2
- SESTD1 | c.*4928G>A | 3'UTR (SNP) | VAF 46/98 reads (47%) | called by muse, mutect2, varscan2
- SHC1 | c.-161G>A | 5'UTR (SNP) | VAF 140/344 reads (41%) | called by muse, mutect2, varscan2
- SLC22A24 | c.*207G>A | 3'UTR (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- SLC25A40 | c.742-97C>T | Intron (SNP) | VAF 14/25 reads (56%) | called by muse, mutect2, varscan2
- SLC25A43 | c.*244G>A | 3'UTR (SNP) | VAF 45/51 reads (88%) | called by muse, mutect2, varscan2
- SLC7A14 | c.*891G>A | 3'UTR (SNP) | VAF 31/87 reads (36%) | called by muse, mutect2, varscan2
- SLK | c.*2992C>T | 3'UTR (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2, varscan2
- SNRPB | c.-63G>A | 5'UTR (SNP) | VAF 90/189 reads (48%) | called by muse, mutect2, varscan2
- SNX13 | c.2627-1095C>T | Intron (SNP) | VAF 25/94 reads (27%) | catalogued as rs1377462785; called by muse, mutect2
- SNX14 | c.140+3963C>T | Intron (SNP) | VAF 93/212 reads (44%) | called by muse, mutect2, varscan2
- SOCS4 | c.*105A>G | 3'UTR (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- SPICE1 | c.*986C>T | 3'UTR (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- SRSF7 | chr2:38751471 G>A | 5'Flank (SNP) | VAF 71/146 reads (49%) | catalogued as rs1039297665, COSV57446500; called by muse, mutect2, varscan2
- STK36 | c.*142G>T | 3'UTR (SNP) | VAF 26/54 reads (48%) | called by muse, mutect2, varscan2
- STT3B | c.*191C>G | 3'UTR (SNP) | VAF 33/134 reads (25%) | catalogued as rs1228668891; called by muse, mutect2, varscan2
- STYX | c.*2603del | 3'UTR (DEL) | VAF 23/56 reads (41%) | called by mutect2, pindel, varscan2
- SUGT1 | chr13:52688039 G>A | 3'Flank (SNP) | VAF 9/14 reads (64%) | called by muse, mutect2, varscan2
- SURF6 | c.*1016A>C | 3'UTR (SNP) | VAF 22/75 reads (29%) | called by muse, mutect2, varscan2
- SUZ12 | c.*1361G>A | 3'UTR (SNP) | VAF 37/60 reads (62%) | called by muse, mutect2, varscan2
- SYNE3 | c.*8217G>A | 3'UTR (SNP) | VAF 21/213 reads (10%) | called by muse, mutect2, varscan2
- TAF5L | c.*211G>A | 3'UTR (SNP) | VAF 96/214 reads (45%) | called by muse, mutect2, varscan2
- TBC1D15 | c.*3121C>T | 3'UTR (SNP) | VAF 27/78 reads (35%) | called by muse, mutect2, varscan2
- TCF19 | c.*233C>A | 3'UTR (SNP) | VAF 41/90 reads (46%) | catalogued as rs1235615160; called by muse, mutect2, varscan2
- TDRP | c.*275C>T | 3'UTR (SNP) | VAF 19/47 reads (40%) | catalogued as rs978208314; called by muse, mutect2, varscan2
- TENM4 | c.*1769G>A | 3'UTR (SNP) | VAF 28/63 reads (44%) | called by muse, mutect2, varscan2
- THAP5 | c.80+1034G>A | Intron (SNP) | VAF 33/46 reads (72%) | called by muse, mutect2, varscan2
- THBS2 | c.1651+97G>A | Intron (SNP) | VAF 31/69 reads (45%) | called by muse, mutect2, varscan2
- TJAP1 | c.580-112G>C | Intron (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2, varscan2
- TLN2 | c.*676G>A | 3'UTR (SNP) | VAF 65/147 reads (44%) | called by muse, mutect2, varscan2
- TLN2 | c.*937G>C | 3'UTR (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- TM4SF18 | c.*196C>T | 3'UTR (SNP) | VAF 18/76 reads (24%) | catalogued as rs1489420994; called by muse, mutect2, varscan2
- TMEM184C | c.*1909G>A | 3'UTR (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- TMEM213 | c.*1786G>C | 3'UTR (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- TMEM250 | c.*1754T>C | 3'UTR (SNP) | VAF 12/38 reads (32%) | called by muse, varscan2
- TMEM250 | c.*1671T>C | 3'UTR (SNP) | VAF 8/44 reads (18%) | called by muse, varscan2
- TMEM42 | c.*398G>A | 3'UTR (SNP) | VAF 27/90 reads (30%) | called by muse, mutect2, varscan2
- TMF1 | c.*2080C>G | 3'UTR (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- TMOD2 | c.*5332G>A | 3'UTR (SNP) | VAF 18/30 reads (60%) | called by muse, mutect2, varscan2
- TNFSF13 | c.-192G>A | 5'UTR (SNP) | VAF 59/118 reads (50%) | called by muse, mutect2, varscan2
- TNFSF4 | c.*2377C>T | 3'UTR (SNP) | VAF 69/69 reads (100%) | called by muse, mutect2, varscan2
- TNKS | c.*4769G>A | 3'UTR (SNP) | VAF 31/72 reads (43%) | called by muse, mutect2, varscan2
- TNS3 | c.*2061C>T | 3'UTR (SNP) | VAF 132/209 reads (63%) | called by muse, mutect2, varscan2
- TOMM20 | c.*941C>G | 3'UTR (SNP) | VAF 285/518 reads (55%) | called by muse, mutect2, varscan2
- TRAP1 | c.705-33C>T | Intron (SNP) | VAF 27/68 reads (40%) | called by muse, mutect2, varscan2
- TRAPPC8 | c.*1152C>T | 3'UTR (SNP) | VAF 44/112 reads (39%) | called by muse, mutect2, varscan2
- TRPC5 | c.*848C>T | 3'UTR (SNP) | VAF 19/21 reads (90%) | called by muse, mutect2, varscan2
- TSC22D4 | c.-246C>A | 5'UTR (SNP) | VAF 12/16 reads (75%) | called by muse, varscan2
- TTC21A | c.2966-99G>A | Intron (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- UBAP2 | c.*251C>G | 3'UTR (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- UBE2H | c.*2710C>A | 3'UTR (SNP) | VAF 56/188 reads (30%) | called by mutect2, varscan2
- UBE2I | c.413+695G>A | Intron (SNP) | VAF 67/157 reads (43%) | called by muse, mutect2, varscan2
- UMAD1 | c.*625C>T | 3'UTR (SNP) | VAF 93/140 reads (66%) | called by muse, mutect2, varscan2
- WDR53 | c.-257G>A | 5'UTR (SNP) | VAF 55/190 reads (29%) | called by muse, mutect2, varscan2
- WRAP73 | c.923-63C>G | Intron (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- WSB1 | c.-229G>C | 5'UTR (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- WTAP | c.*439G>A | 3'UTR (SNP) | VAF 23/46 reads (50%) | called by muse, mutect2, varscan2
- XK | c.*1137G>A | 3'UTR (SNP) | VAF 14/15 reads (93%) | catalogued as rs1043509596; called by muse, mutect2, varscan2
- YIPF4 | c.*3728C>T | 3'UTR (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- ZBTB40 | c.*373C>T | 3'UTR (SNP) | VAF 28/60 reads (47%) | called by muse, mutect2, varscan2
- ZMAT3 | c.*2136C>T | 3'UTR (SNP) | VAF 42/122 reads (34%) | called by muse, mutect2, varscan2
- ZMIZ2 | c.*493C>T | 3'UTR (SNP) | VAF 44/149 reads (30%) | catalogued as rs932380337; called by muse, mutect2, varscan2
- ZNF148 | c.*2271G>A | 3'UTR (SNP) | VAF 35/114 reads (31%) | called by muse, mutect2, varscan2
- ZNF280D | c.381+102C>G | Intron (SNP) | VAF 97/204 reads (48%) | called by muse, mutect2, varscan2
- ZNF317 | c.-174G>A | 5'UTR (SNP) | VAF 95/200 reads (48%) | called by muse, mutect2, varscan2
- ZNF354C | c.*1777G>A | 3'UTR (SNP) | VAF 29/68 reads (43%) | called by muse, mutect2, varscan2
- ZNF543 | c.-10G>A | 5'UTR (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- ZNF556 | c.-25C>T | 5'UTR (SNP) | VAF 24/55 reads (44%) | called by muse, mutect2, varscan2
